Somatic mutation profile of tumor specimen TCGA-HC-7211-01A (aliquot TCGA-HC-7211-01A-11D-2114-08) from TCGA case TCGA-HC-7211, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,768 days).
Specimen TCGA-HC-7211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0345575-5d54-4d58-853a-6f9d1c9785bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7211-11A (Solid Tissue Normal), aliquot TCGA-HC-7211-11A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/980b794b-ca1d-43b8-8cd9-f7405da80d41

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QL2 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV55606177; called by muse, mutect2, varscan2
- CHD5 | c.5716C>T p.R1906C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1349809904, COSV52409821; called by muse, mutect2, varscan2
- DCAF4L1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60786771; called by muse, mutect2
- ENTPD6 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV61751108; called by muse, mutect2, varscan2
- FBN1 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM158978, COSV57311581; called by muse, mutect2, varscan2
- GAS2L2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs144024552; called by muse, mutect2, varscan2
- MED15 | c.1113G>C p.Q371H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.452); catalogued as rs771734946, COSV53027539; called by muse, mutect2, varscan2
- RAPGEF6 | c.4084C>T p.R1362C | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147775864; called by muse, mutect2, varscan2
- RPL28 | c.194A>T p.K65M | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59804486; called by muse, mutect2, varscan2
- TAF5 | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60856501; called by muse, mutect2, varscan2
- TNFAIP6 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54640189; called by muse, mutect2
- TRPC4 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1287965364, COSV58993391; called by muse, mutect2, varscan2
- ZNF695 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV60585005; called by muse, mutect2
- PEX12 | c.774dup p.Q259Afs*4 | Frame Shift Ins (INS) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.813G>T p.R271= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV60909990; called by muse, mutect2, varscan2
- BCL11A | c.462C>T p.H154= (on ENST00000335712 / NM_001365609.1; = p.H188= on NM_018014.4) | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs201796557; called by muse, mutect2, varscan2
- OBSCN | c.6879G>A p.V2293= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV52750640; called by muse, mutect2, varscan2
